Gene-level copy-number profile of tumor specimen TCGA-A7-A26E-01A from TCGA case TCGA-A7-A26E, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.9 years (26,274 days).
Specimen TCGA-A7-A26E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ba887b57-a7ae-4bb7-b7fb-8e37f5e0cc20.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A26E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac5bc2e2-9b31-49d2-9888-365c084e3034

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,872; copy number 2: 51,338; copy number 3: 2,610.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A26E-01A-11D-A275-01): tumor purity 0.72, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,872. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
